Surgical pathology report (de-identified scan), TCGA case TCGA-A4-7585, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-7585-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Left kidney, radical nephrectomy:
Infiltrating renal carcinoma.

Tumor Characteristics:

1. Histologic type: Papillary (chromophil) renal cell carcinoma, oncocytic variant, with extensive degenerative changes and necrosis.
2. Tumor site: Left kidney.
3. Macroscopic extent of tumor: Tumor involves perinephric adipose tissue.
4. Nuclear grade: Fuhrman grade: 2/4.
5. Lymphovascular space invasion: Not identified.
6. Transcapsular invasion: Tumor focally infiltrates through renal capsule to involve perinephritic adipose tissue.
7. Renal vein invasion: Not identified.
8. Venacaval invasion: Not resected.
9. Adrenal gland: Not identified.

Surgical Margin Status:

1. Soft tissue margins: Negative for tumor.
2. Ureteral margin: Negative for tumor.
3. Vascular Margins: Negative for tumor.

Lymph Node Status:

No lymph nodes identified.

Other Significant Findings:

1. pTNM stage: T3a NX MX, stage III.

Staging Sheet

CLINICAL INFORMATION

[page 2 of 2]
CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Left renal mass

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Left kidney

SPECIMEN DATA

GROSS DESCRIPTION:

Received in formalin labeled [REDACTED] and #1 is a [REDACTED] nephrectomy specimen, consisting of a 10.5 x 5.8 x 3.1 cm kidney, with a moderate amount of attached perinephric fat. The specimen has been previously bivalved. There is a minimal amount of identifiable ureter and a minimal amount of possible renal vein and artery. The capsule is smooth and tan. The cut surface consists of a 5.2 x 4.5 x 4.1 cm focally cystic tan red to orange mass, which diffusely involves the adipose tissue, and abuts the inked perinephric fat. The adipose tissue adjacent to the mass has a glistening yellow appearance. The remainder of the cut surface consists of tan pink parenchyma, with a 0.4 cm tan brown cyst. The cortical medullary junction is ill defined. The urothelium is gray white. No enlarged lymph nodes are identified. The adrenal gland is not present. The specimen is inked, serially sectioned, and representative sections are submitted as labeled: 1--ureterovascular margins; 2 to 4--mass to inked perinephric fat; 5--mass; 6--mass to uninvolved parenchyma; 7--glistening yellow adipose tissue adjacent to mass; 8--uninvolved parenchyma to include cyst; 9--uninvolved parenchyma. The blocks are labeled [REDACTED]. Also received in the same container are two orange cassettes labeled A and C and a green and yellow cassette labeled [REDACTED] for genomic research study.

Source: NCI Genomic Data Commons file 959d823d-6a06-4624-b148-47153136cfb3 (TCGA-A4-7585.2AD46264-0E7A-489B-85E5-2AB6F55AB44C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).